Somatic mutation profile of tumor specimen TCGA-NC-A5HD-01A (aliquot TCGA-NC-A5HD-01A-11D-A26M-08) from TCGA case TCGA-NC-A5HD, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 79.2 years (28,916 days).
Specimen TCGA-NC-A5HD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dc780f6b-ed15-484d-8d41-712093c9b043.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-NC-A5HD-10A (Blood Derived Normal), aliquot TCGA-NC-A5HD-10A-01D-A26K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e05d9395-64a2-4b23-b05f-2533e1a55726

The open-access MAF lists 497 somatic variants for this specimen: 405 protein-altering or splice-affecting, 79 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 346, Silent 79, Nonsense Mutation 30, Frame Shift Del 13, Splice Site 7, RNA 6, Frame Shift Ins 4, Intron 3, Splice Region 2, Translation Start Site 1, Nonstop Mutation 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CRB1 | c.3307G>A p.G1103R | Missense Mutation (SNP) | VAF 59/130 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as rs62636275, CM040718, CM057655, COSV100958048, COSV66328782, COSV66330317; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.838A>G p.R280G | Missense Mutation (SNP) | VAF 17/35 reads (49%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs753660142, COSV52662754, COSV52708728, COSV52851287; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ABCA4 | c.35G>A p.W12* | Nonsense Mutation (SNP) | VAF 40/108 reads (37%) | catalogued as COSV100933335; called by muse, mutect2, varscan2
- ABCB5 | c.2272G>T p.G758C (on ENST00000404938 / NM_001163941.2; = p.G313C on NM_178559.6) | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs373783857, COSV51723348, COSV99327421; called by muse, mutect2, varscan2
- ABCD2 | c.1126G>C p.G376R | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT tolerated (0.25); PolyPhen benign (0.035); catalogued as COSV100429872; called by muse, mutect2, varscan2
- ABCD3 | c.1309G>C p.D437H | Missense Mutation (SNP) | VAF 47/259 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100931484; called by muse, mutect2, varscan2
- AC093155.3 | c.827C>G p.S276* | Nonsense Mutation (SNP) | VAF 8/42 reads (19%) | catalogued as rs867213630, COSV100777886; called by muse, mutect2, varscan2
- ACACB | c.1438-2A>G p.X480_splice | Splice Site (SNP) | VAF 8/14 reads (57%) | catalogued as rs994484216, COSV100623387; called by muse, mutect2, varscan2
- ACTN3 | c.1307A>G p.Y436C | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1470844170, COSV100074547; called by muse, mutect2, varscan2
- ADCY2 | c.2570A>G p.E857G | Missense Mutation (SNP) | VAF 14/117 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100604571; called by muse, mutect2
- ADD2 | c.1775C>G p.S592* | Nonsense Mutation (SNP) | VAF 22/53 reads (42%) | catalogued as COSV100036675; called by muse, mutect2, varscan2
- ADGRA1 | c.500+1G>T p.X167_splice | Splice Site (SNP) | VAF 11/15 reads (73%) | catalogued as COSV101192753; called by muse, mutect2, varscan2
- ADGRA3 | c.3101C>G p.T1034R | Missense Mutation (SNP) | VAF 52/90 reads (58%) | SIFT deleterious (0.04); PolyPhen benign (0.122); catalogued as COSV99293883; called by muse, mutect2, varscan2
- ADGRB1 | c.271G>A p.V91M | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.188); catalogued as COSV100030567, COSV60102610; called by muse, mutect2, varscan2
- ADGRG2 | c.1205T>A p.I402N (on ENST00000379869 / NM_001079858.3; = p.I399N on NM_005756.4) | Missense Mutation (SNP) | VAF 81/111 reads (73%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV100492836; called by muse, mutect2, varscan2
- ADGRL2 | c.1607G>T p.G536V | Missense Mutation (SNP) | VAF 38/107 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV99592015; called by muse, mutect2, varscan2
- ADGRV1 | c.971A>T p.D324V | Missense Mutation (SNP) | VAF 41/73 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101316676; called by muse, mutect2, varscan2
- ADRA1A | c.4G>A p.V2M | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.459); catalogued as rs1239344489, COSV99372607; called by muse, mutect2, varscan2
- AGL | c.359A>G p.H120R | Missense Mutation (SNP) | VAF 124/335 reads (37%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs758162985, COSV99650211; called by muse, mutect2, varscan2
- AHRR | c.1273T>C p.S425P | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV100328160; called by muse, mutect2, varscan2
- AIFM3 | c.167C>G p.S56C | Missense Mutation (SNP) | VAF 58/90 reads (64%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.439); catalogued as COSV100105231; called by muse, mutect2, varscan2
- ALDH9A1 | c.1557A>T p.*519Cext*27 | Nonstop Mutation (SNP) | VAF 24/114 reads (21%) | catalogued as COSV100699329; called by mutect2, varscan2
- ALMS1 | c.5800C>G p.P1934A | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.259); catalogued as COSV100044093; called by muse, mutect2, varscan2
- AMDHD1 | c.977G>A p.G326E | Missense Mutation (SNP) | VAF 48/128 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57139595; called by muse, mutect2, varscan2
- AMOTL1 | c.2309A>T p.K770M | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100504833; called by muse, mutect2, varscan2
- ANO5 | c.923G>T p.G308V | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100202353, COSV61091154; called by muse, mutect2, varscan2
- AP1G1 | c.2107+1G>T p.X703_splice | Splice Site (SNP) | VAF 33/92 reads (36%) | catalogued as COSV100251162; called by muse, mutect2, varscan2
- AP1G1 | c.2107G>A p.G703S | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT tolerated (0.9); PolyPhen benign (0.001); catalogued as COSV55487250, COSV55490097; called by muse, mutect2, varscan2
- AP3B1 | c.1345C>A p.L449M | Missense Mutation (SNP) | VAF 50/80 reads (63%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.816); catalogued as COSV99672670; called by muse, mutect2, varscan2
- APBA2 | c.311G>C p.C104S | Missense Mutation (SNP) | VAF 80/129 reads (62%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV101382611; called by muse, mutect2, varscan2
- APOB | c.10554C>A p.N3518K | Missense Mutation (SNP) | VAF 47/184 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.138); catalogued as COSV99268657; called by muse, mutect2, varscan2
- APOB | c.1668T>A p.D556E | Missense Mutation (SNP) | VAF 42/162 reads (26%) | SIFT tolerated (0.58); PolyPhen benign (0.015); catalogued as COSV99268658; called by muse, mutect2, varscan2
- ARFGEF3 | c.1228G>A p.G410S | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.862); catalogued as COSV99294980; called by muse, mutect2, varscan2
- ARHGAP5 | c.3277del p.E1093Nfs*34 | Frame Shift Del (DEL) | VAF 42/93 reads (45%) | catalogued as COSV61534517; called by mutect2, pindel, varscan2
- ARHGEF26 | c.1293G>C p.Q431H | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV100726706; called by muse, mutect2, varscan2
- ATP8B4 | c.2000A>T p.N667I | Missense Mutation (SNP) | VAF 39/57 reads (68%) | SIFT deleterious (0); PolyPhen possibly damaging (0.595); catalogued as COSV99468034; called by muse, mutect2, varscan2
- BTBD10 | c.930A>G p.I310M | Missense Mutation (SNP) | VAF 83/151 reads (55%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.89); catalogued as COSV99533995; called by muse, mutect2, varscan2
- BTRC | c.528G>T p.L176F (on ENST00000370187 / NM_033637.4; = p.L140F on NM_003939.5) | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.774); catalogued as COSV100926642; called by muse, mutect2, varscan2
- C1orf116 | c.1604C>T p.T535M | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.058); catalogued as rs562853562, COSV100848043; called by mutect2, varscan2
- C20orf194 | c.1787C>T p.S596F | Missense Mutation (SNP) | VAF 32/118 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV99331704; called by muse, mutect2, varscan2
- C7 | c.1982G>T p.G661V | Missense Mutation (SNP) | VAF 54/225 reads (24%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.643); catalogued as rs1313401268, COSV100496758; called by muse, mutect2, varscan2
- CACNA1A | c.3390C>A p.N1130K | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT tolerated (0.41); PolyPhen benign (0.15); catalogued as COSV100803435; called by muse, mutect2, varscan2
- CACNA1E | c.3762C>G p.I1254M | Missense Mutation (SNP) | VAF 20/125 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100705830; called by muse, mutect2, varscan2
- CACNG3 | c.940C>A p.P314T | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99136244, COSV99137342; called by muse, mutect2, varscan2
- CADM4 | c.983G>A p.G328D | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.444); catalogued as rs867442079, COSV99731734; called by muse, mutect2
- CAMKK1 | c.607C>A p.L203M | Missense Mutation (SNP) | VAF 27/54 reads (50%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as COSV99340642; called by muse, mutect2, varscan2
- CARMIL1 | c.577del p.E193Nfs*2 | Frame Shift Del (DEL) | VAF 9/27 reads (33%) | catalogued as COSV100276586; called by mutect2, pindel, varscan2
- CASP5 | c.268C>T p.H90Y | Missense Mutation (SNP) | VAF 46/254 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.403); catalogued as COSV99508214; called by muse, mutect2, varscan2
- CD1A | c.693G>T p.K231N | Missense Mutation (SNP) | VAF 52/119 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99192666; called by muse, mutect2, varscan2
- CDH1 | c.2549C>T p.S850F | Missense Mutation (SNP) | VAF 20/109 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99932810; called by muse, mutect2, varscan2
- CDH10 | c.2213A>G p.Y738C | Missense Mutation (SNP) | VAF 90/262 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100053489; called by muse, mutect2, varscan2
- CDH10 | c.52C>A p.H18N | Missense Mutation (SNP) | VAF 16/154 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV100053492; called by muse, mutect2, varscan2
- CDK17 | c.62C>A p.S21* | Nonsense Mutation (SNP) | VAF 30/72 reads (42%) | catalogued as COSV99703197; called by muse, mutect2, varscan2
- CEP164 | c.1810G>C p.E604Q | Missense Mutation (SNP) | VAF 45/129 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.795); catalogued as COSV54043580, COSV99634141; called by muse, mutect2, varscan2
- CERKL | c.370A>T p.I124F | Missense Mutation (SNP) | VAF 42/96 reads (44%) | SIFT tolerated (0.46); PolyPhen benign (0.091); catalogued as rs377039657, COSV100184281; called by muse, mutect2, varscan2
- CFAP91 | c.1540G>C p.E514Q | Missense Mutation (SNP) | VAF 57/142 reads (40%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.997); catalogued as COSV99847596; called by muse, mutect2, varscan2
- CFH | c.2911G>A p.A971T | Missense Mutation (SNP) | VAF 68/199 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.011); catalogued as COSV66408850, COSV66409880, COSV66415821; called by muse, mutect2, varscan2
- CHID1 | c.112-2A>T p.X38_splice | Splice Site (SNP) | VAF 37/54 reads (69%) | catalogued as COSV100060305; called by muse, mutect2, varscan2
- CHRD | c.556C>T p.R186* | Nonsense Mutation (SNP) | VAF 15/126 reads (12%) | catalogued as COSV99200987; called by muse, mutect2, varscan2
- CLCA1 | c.2071C>T p.Q691* | Nonsense Mutation (SNP) | VAF 25/66 reads (38%) | catalogued as COSV99322066; called by muse, mutect2, varscan2
- CLNK | c.182C>A p.A61E | Missense Mutation (SNP) | VAF 73/134 reads (54%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV99906058; called by muse, mutect2, varscan2
- CNBD2 | c.619G>T p.E207* | Nonsense Mutation (SNP) | VAF 37/130 reads (28%) | catalogued as rs1267705414, COSV100839195; called by muse, mutect2, varscan2
- COL12A1 | c.3213G>T p.M1071I | Missense Mutation (SNP) | VAF 24/158 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV100486784; called by muse, mutect2, varscan2
- COL15A1 | c.1550C>T p.P517L | Missense Mutation (SNP) | VAF 14/22 reads (64%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.108); catalogued as COSV66647197; called by muse, varscan2
- COL19A1 | c.294G>T p.E98D | Missense Mutation (SNP) | VAF 42/164 reads (26%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as COSV59577801; called by muse, mutect2, varscan2
- COL1A2 | c.19A>T p.T7S | Missense Mutation (SNP) | VAF 54/218 reads (25%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.003); catalogued as COSV99801469; called by muse, mutect2, varscan2
- COL24A1 | c.1741C>A p.P581T | Missense Mutation (SNP) | VAF 84/215 reads (39%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.513); catalogued as COSV100994180; called by muse, mutect2, varscan2
- COL4A2 | c.1729C>T p.P577S | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.005); catalogued as COSV100847532; called by muse, mutect2, varscan2
- COL4A5 | c.3115G>T p.G1039C | Missense Mutation (SNP) | VAF 24/36 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM960383, COSV100090512; called by muse, mutect2, varscan2
- COQ5 | c.659G>T p.R220L | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99942577; called by muse, mutect2, varscan2
- CR2 | c.419C>A p.P140Q | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65506334, COSV65508645; called by muse, mutect2, varscan2
- CSF2RB | c.1541G>T p.W514L | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.39); PolyPhen benign (0.012); catalogued as COSV53255564, COSV99454635; called by muse, mutect2, varscan2
- CTTN | c.796A>T p.K266* | Nonsense Mutation (SNP) | VAF 91/363 reads (25%) | catalogued as COSV100098501; called by muse, mutect2, varscan2
- CTTNBP2 | c.1921G>T p.A641S | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT tolerated (0.85); PolyPhen benign (0.01); catalogued as COSV99355103; called by muse, mutect2, varscan2
- CUBN | c.6449G>T p.G2150V | Missense Mutation (SNP) | VAF 29/50 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64717728, COSV64722860; called by muse, mutect2, varscan2
- DAW1 | c.612G>C p.W204C | Missense Mutation (SNP) | VAF 37/91 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs553945416, COSV100006613, COSV59365579; called by muse, mutect2, varscan2
- DCT | c.1048G>C p.A350P | Missense Mutation (SNP) | VAF 24/40 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100986327; called by muse, mutect2, varscan2
- DDR1 | c.653A>G p.H218R | Missense Mutation (SNP) | VAF 26/43 reads (60%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as COSV100242260; called by muse, mutect2, varscan2
- DDX54 | c.1517G>T p.R506L | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as COSV100014277; called by muse, mutect2, varscan2
- DDX60 | c.2986G>T p.G996C | Missense Mutation (SNP) | VAF 79/115 reads (69%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.599); catalogued as COSV101190763; called by muse, mutect2, varscan2
- DEPP1 | c.335C>T p.S112F | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.04); catalogued as COSV100024509; called by muse, mutect2, varscan2
- DICER1 | c.4738C>A p.Q1580K | Missense Mutation (SNP) | VAF 75/190 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.93); catalogued as COSV100602659; called by muse, mutect2, varscan2
- DMBX1 | c.343G>C p.V115L | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.928); catalogued as COSV100760956; called by muse, mutect2, varscan2
- DNAH14 | c.818T>C p.L273S (on ENST00000445597; = p.L146S on NM_144989.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 35/187 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.142); catalogued as COSV100836002; called by muse, mutect2, varscan2
- DNAH3 | c.3269G>A p.W1090* | Nonsense Mutation (SNP) | VAF 89/135 reads (66%) | catalogued as COSV99771293; called by muse, mutect2, varscan2
- DNAH7 | c.5169G>A p.M1723I | Missense Mutation (SNP) | VAF 54/140 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.094); catalogued as COSV100418141; called by muse, mutect2, varscan2
- DNAJC28 | c.748A>T p.N250Y | Missense Mutation (SNP) | VAF 126/183 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100074787, COSV58721846; called by muse, mutect2, varscan2
- DOCK2 | c.743A>T p.N248I | Missense Mutation (SNP) | VAF 48/76 reads (63%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV99916195; called by muse, mutect2, varscan2
- DPP10 | c.1823G>T p.G608V | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100072995; called by muse, mutect2, varscan2
- DSG1 | c.2549C>A p.S850Y | Missense Mutation (SNP) | VAF 113/175 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV99936704; called by muse, mutect2, varscan2
- DUSP29 | c.177G>A p.W59* | Nonsense Mutation (SNP) | VAF 24/45 reads (53%) | catalogued as COSV100633242; called by muse, mutect2
- EDDM3B | c.166G>A p.E56K | Missense Mutation (SNP) | VAF 55/92 reads (60%) | SIFT tolerated (0.17); PolyPhen benign (0.127); catalogued as COSV100460928, COSV58746990; called by muse, mutect2, varscan2
- EFEMP2 | c.525C>G p.H175Q | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT tolerated (0.99); PolyPhen benign (0.276); catalogued as COSV100337438; called by muse, mutect2, varscan2
- EFNB2 | c.782C>G p.P261R | Missense Mutation (SNP) | VAF 33/60 reads (55%) | SIFT tolerated (0.15); PolyPhen benign (0.439); catalogued as COSV55367761, COSV99809013; called by muse, mutect2, varscan2
- ELFN2 | c.1550C>G p.P517R | Missense Mutation (SNP) | VAF 33/103 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101297669; called by muse, mutect2, varscan2
- ELL2 | c.814T>G p.W272G | Missense Mutation (SNP) | VAF 82/127 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99427993; called by muse, mutect2, varscan2
- EMCN | c.161C>T p.T54I | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as COSV99598834; called by muse, mutect2, varscan2
- EPHA3 | c.198G>T p.R66S | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1354537650, COSV60692726; called by muse, mutect2, varscan2
- EPHA6 | c.964T>A p.S322T | Missense Mutation (SNP) | VAF 167/428 reads (39%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.737); catalogued as COSV101066084; called by muse, mutect2, varscan2
- ERICH1 | c.1120G>T p.D374Y | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV100033176; called by muse, mutect2, varscan2
- ERICH3 | c.3880C>A p.P1294T | Missense Mutation (SNP) | VAF 32/154 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.01); catalogued as COSV100446082; called by muse, mutect2, varscan2
- ERP44 | c.931A>G p.I311V | Missense Mutation (SNP) | VAF 44/68 reads (65%) | SIFT deleterious (0.01); PolyPhen benign (0.02); catalogued as rs753065804, COSV99316741; called by muse, mutect2, varscan2
- ETNPPL | c.454T>C p.Y152H | Missense Mutation (SNP) | VAF 65/107 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV99625735; called by muse, mutect2, varscan2
- ETV3L | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV101485631; called by muse, mutect2, varscan2
- FAM171B | c.1968G>T p.Q656H | Missense Mutation (SNP) | VAF 42/134 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV100489124; called by muse, mutect2, varscan2
- FAM71B | c.83T>A p.L28Q | Missense Mutation (SNP) | VAF 81/137 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100262363; called by muse, mutect2, varscan2
- FAM91A1 | c.214C>G p.R72G | Missense Mutation (SNP) | VAF 140/167 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as CM124416, COSV100593859, COSV58236755; called by muse, mutect2, varscan2
- FAP | c.1331G>T p.R444M | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.973); catalogued as COSV51868733, COSV99502624; called by muse, mutect2, varscan2
- FASN | c.5521C>T p.R1841C | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100148450; called by muse, mutect2, varscan2
- FBN2 | c.8105C>A p.S2702Y | Missense Mutation (SNP) | VAF 76/126 reads (60%) | SIFT tolerated (1); PolyPhen possibly damaging (0.58); catalogued as COSV99331382; called by muse, mutect2, varscan2
- FDPS | c.769A>C p.K257Q | Missense Mutation (SNP) | VAF 38/105 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV100756321; called by muse, mutect2, varscan2
- FER | c.270G>C p.E90D | Missense Mutation (SNP) | VAF 53/89 reads (60%) | SIFT tolerated (0.24); PolyPhen benign (0.04); catalogued as COSV99814242; called by muse, mutect2, varscan2
- FGD4 | c.505G>C p.E169Q | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV99847742; called by muse, mutect2, varscan2
- FGF12 | c.382G>T p.A128S (on ENST00000454309 / NM_021032.5; = p.A66S on NM_004113.6) | Missense Mutation (SNP) | VAF 54/429 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.835); catalogued as COSV53191037; called by muse, varscan2
- FGF6 | c.190G>T p.G64W | Missense Mutation (SNP) | VAF 34/151 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.046); catalogued as COSV57404638, COSV57405731; called by muse, mutect2, varscan2
- FNBP4 | c.544G>A p.A182T | Missense Mutation (SNP) | VAF 44/72 reads (61%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV99772068; called by muse, mutect2, varscan2
- FRK | c.998A>C p.D333A | Missense Mutation (SNP) | VAF 58/117 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV101606685; called by muse, mutect2, varscan2
- FUCA2 | c.1205G>A p.W402* | Nonsense Mutation (SNP) | VAF 21/61 reads (34%) | catalogued as COSV99136292; called by muse, mutect2, varscan2
- FZD1 | c.476T>G p.V159G | Missense Mutation (SNP) | VAF 57/156 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV99842855; called by muse, mutect2, varscan2
- FZD9 | c.1711G>T p.A571S | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as COSV59993226; called by muse, mutect2, varscan2
- GAD2 | c.689G>C p.W230S | Missense Mutation (SNP) | VAF 41/66 reads (62%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV99394253; called by muse, mutect2, varscan2
- GAD2 | c.690G>A p.W230* | Nonsense Mutation (SNP) | VAF 41/65 reads (63%) | catalogued as COSV52162227, COSV99393277; called by muse, mutect2, varscan2
- GBP6 | c.1413G>C p.E471D | Missense Mutation (SNP) | VAF 68/155 reads (44%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.969); catalogued as COSV100969728; called by muse, mutect2, varscan2
- GBP7 | c.1015G>T p.A339S | Missense Mutation (SNP) | VAF 50/156 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0.34); catalogued as COSV54008415, COSV99643597; called by muse, mutect2, varscan2
- GGA1 | c.1018C>T p.R340C | Missense Mutation (SNP) | VAF 46/97 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs768179026, COSV100289937; called by muse, mutect2, varscan2
- GIMAP5 | c.310del p.Y104Tfs*14 | Frame Shift Del (DEL) | VAF 36/113 reads (32%) | catalogued as COSV99070865; called by mutect2, pindel, varscan2
- GLG1 | c.3190G>C p.D1064H | Missense Mutation (SNP) | VAF 20/144 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99216403; called by muse, mutect2, varscan2
- GLI3 | c.3127A>T p.S1043C | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.447); catalogued as COSV101230148; called by muse, mutect2, varscan2
- GLOD5 | c.287C>G p.P96R | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as COSV100297556; called by muse, mutect2, varscan2
- GLRX3 | c.772-2A>G p.X258_splice | Splice Site (SNP) | VAF 32/60 reads (53%) | catalogued as COSV58691889; called by muse, mutect2, varscan2
- GOLGA6B | c.908A>G p.E303G | Missense Mutation (SNP) | VAF 23/169 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as COSV101406963; called by muse, mutect2, varscan2
- GOLGA6B | c.1463T>C p.L488P | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.214); catalogued as COSV101406964; called by muse, mutect2, varscan2
- GPM6A | c.530T>G p.L177R | Missense Mutation (SNP) | VAF 43/62 reads (69%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.845); catalogued as COSV99706009; called by muse, mutect2, varscan2
- GPR158 | c.31T>C p.C11R | Missense Mutation (SNP) | VAF 37/58 reads (64%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.087); catalogued as COSV100894421; called by muse, mutect2, varscan2
- GPRC5C | c.572G>T p.R191L (on ENST00000652232; = p.R146L on NM_018653.4) | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.932); catalogued as COSV100703047, COSV61237544; called by muse, mutect2, varscan2
- GPRC6A | c.1472T>A p.M491K | Missense Mutation (SNP) | VAF 33/137 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.191); catalogued as COSV100114890; called by muse, mutect2, varscan2
- GRID2 | c.1274T>G p.L425R | Missense Mutation (SNP) | VAF 34/106 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99948123; called by muse, mutect2, varscan2
- GRIN2A | c.1346G>C p.G449A | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.899); catalogued as COSV100411340, COSV58044843; called by muse, mutect2, varscan2
- GRIN2B | c.16G>T p.E6* | Nonsense Mutation (SNP) | VAF 18/39 reads (46%) | catalogued as rs750494985, COSV101663226; called by muse, mutect2, varscan2
- GTDC1 | c.552A>T p.L184F | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV99602199; called by muse, mutect2, varscan2
- GTF3C2 | c.2218A>G p.N740D | Missense Mutation (SNP) | VAF 57/120 reads (48%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as COSV99273409; called by muse, mutect2, varscan2
- GUCY1A2 | c.1849A>G p.I617V | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.181); catalogued as COSV99977528; called by muse, mutect2, varscan2
- GZMB | c.215T>C p.V72A | Missense Mutation (SNP) | VAF 41/72 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV99362600; called by muse, mutect2, varscan2
- HAUS5 | c.1501G>C p.G501R | Missense Mutation (SNP) | VAF 59/93 reads (63%) | SIFT tolerated (0.12); PolyPhen benign (0.204); catalogued as COSV99178865; called by muse, mutect2, varscan2
- HECW1 | c.1075C>A p.P359T | Missense Mutation (SNP) | VAF 32/68 reads (47%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.007); catalogued as COSV101224404; called by muse, mutect2, varscan2
- HECW1 | c.1076C>A p.P359H | Missense Mutation (SNP) | VAF 32/68 reads (47%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.707); catalogued as COSV101224405; called by muse, mutect2, varscan2
- HFM1 | c.323G>A p.G108E | Missense Mutation (SNP) | VAF 34/113 reads (30%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); catalogued as COSV54036269, COSV99647053; called by muse, mutect2, varscan2
- HIPK2 | c.615G>T p.L205F | Missense Mutation (SNP) | VAF 53/100 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100702652; called by muse, mutect2, varscan2
- HJURP | c.2200G>C p.E734Q | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0.202); catalogued as COSV101082752; called by muse, mutect2, varscan2
- HPX | c.1141T>C p.W381R | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.779); catalogued as COSV99793597; called by muse, mutect2, varscan2
- HS3ST4 | c.782C>A p.T261N | Missense Mutation (SNP) | VAF 26/45 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.706); catalogued as COSV100503369; called by muse, mutect2, varscan2
- HSD17B11 | c.450+1G>C p.X150_splice | Splice Site (SNP) | VAF 68/114 reads (60%) | catalogued as COSV100839649; called by muse, mutect2, varscan2
- IARS1 | c.777G>T p.M259I | Missense Mutation (SNP) | VAF 78/125 reads (62%) | SIFT deleterious (0.04); PolyPhen benign (0.098); catalogued as COSV100986910; called by muse, mutect2, varscan2
- IKZF1 | c.1288G>A p.E430K | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV100498866; called by muse, mutect2, varscan2
- IKZF3 | c.1204C>G p.Q402E | Missense Mutation (SNP) | VAF 28/136 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.028); catalogued as COSV99499511, COSV99500258; called by muse, mutect2, varscan2
- INSIG2 | c.592G>C p.A198P | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55522821, COSV99830698; called by muse, mutect2, varscan2
- INSYN1 | c.830A>T p.Q277L | Missense Mutation (SNP) | VAF 129/222 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101138830; called by muse, mutect2, varscan2
- IQGAP3 | c.4586G>T p.G1529V | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV100752459; called by muse, mutect2, varscan2
- IQGAP3 | c.3778G>C p.E1260Q | Missense Mutation (SNP) | VAF 31/100 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); catalogued as COSV100752462; called by muse, mutect2, varscan2
- IRF5 | c.1400C>G p.S467C | Missense Mutation (SNP) | VAF 41/99 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.238); catalogued as COSV99978049; called by muse, mutect2, varscan2
- ITM2A | c.487A>G p.M163V | Missense Mutation (SNP) | VAF 25/44 reads (57%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as COSV100964502; called by muse, mutect2, varscan2
- KALRN | c.5385T>A p.D1795E (on ENST00000360013 / NM_001024660.4; = p.D98E on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 52/164 reads (32%) | SIFT tolerated (0.99); PolyPhen benign (0.001); catalogued as COSV99363207; called by muse, mutect2, varscan2
- KCNK15 | c.756C>G p.D252E | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.024); catalogued as COSV100865236; called by muse, mutect2, varscan2
- KCNMA1 | c.985G>A p.E329K | Missense Mutation (SNP) | VAF 185/303 reads (61%) | SIFT tolerated (0.85); PolyPhen benign (0.042); catalogued as COSV99700433; called by muse, mutect2, varscan2
- KCNT2 | c.2119T>C p.Y707H | Missense Mutation (SNP) | VAF 52/331 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV99657462; called by muse, mutect2, varscan2
- KCNV1 | c.325G>A p.A109T | Missense Mutation (SNP) | VAF 21/37 reads (57%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as COSV52087430; called by muse, mutect2, varscan2
- KDM5B | c.3517G>A p.D1173N | Missense Mutation (SNP) | VAF 64/182 reads (35%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as COSV99351604; called by muse, mutect2, varscan2
- KIF13B | c.2551G>A p.G851S | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.099); catalogued as COSV101568724; called by muse, mutect2, varscan2
- KIF14 | c.2371G>T p.G791* | Nonsense Mutation (SNP) | VAF 23/56 reads (41%) | catalogued as COSV100951119; called by muse, mutect2, varscan2
- KIF16B | c.3487C>G p.L1163V | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.676); catalogued as COSV100735019; called by muse, mutect2, varscan2
- KIFC3 | c.1418C>T p.A473V | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs1016234011, COSV101109440, COSV65552009; called by muse, mutect2, varscan2
- KLHL7 | c.1487A>T p.D496V (on ENST00000339077 / NM_001031710.3; = p.D448V on NM_018846.5) | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.995); catalogued as COSV100178527; called by muse, mutect2, varscan2
- KMT2D | c.12760del p.Q4254Rfs*24 | Frame Shift Del (DEL) | VAF 24/88 reads (27%) | catalogued as COSV56417227; called by mutect2, pindel, varscan2
- KNDC1 | c.1295C>G p.A432G | Missense Mutation (SNP) | VAF 21/34 reads (62%) | SIFT tolerated (0.47); PolyPhen benign (0.038); catalogued as COSV100466527; called by muse, mutect2, varscan2
- KRTAP13-4 | c.295T>C p.S99P | Missense Mutation (SNP) | VAF 20/31 reads (65%) | SIFT deleterious (0.02); PolyPhen benign (0.2); catalogued as rs994058989, COSV100481867; called by muse, mutect2, varscan2
- KRTAP4-2 | c.229C>G p.R77G | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV100894571; called by muse, mutect2, varscan2
- L3MBTL1 | c.2255G>T p.W752L (on ENST00000418998 / NM_001377303.1; = p.W662L on NM_015478.7) | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100917074; called by muse, mutect2, varscan2
- LAP3 | c.1414G>T p.V472L | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); catalogued as COSV104389211, COSV99884719; called by muse, mutect2, varscan2
- LDHC | c.73A>G p.I25V | Missense Mutation (SNP) | VAF 55/95 reads (58%) | SIFT tolerated (1); PolyPhen benign (0.058); catalogued as rs1454281645, COSV99772726; called by muse, mutect2, varscan2
- LHX8 | c.391A>T p.R131W | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99634596; called by muse, mutect2, varscan2
- LHX9 | c.407G>T p.C136F | Missense Mutation (SNP) | VAF 36/78 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100436110; called by muse, mutect2, varscan2
- LILRA6 | c.1343T>A p.L448H | Missense Mutation (SNP) | VAF 31/37 reads (84%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99558732; called by muse, mutect2, varscan2
- LLGL2 | c.1252A>G p.M418V | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as COSV99390658; called by muse, mutect2, varscan2
- LMNTD1 | c.130A>G p.M44V | Missense Mutation (SNP) | VAF 43/93 reads (46%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as COSV99280489; called by muse, mutect2, varscan2
- LRP1B | c.2513G>T p.G838V | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.49); catalogued as COSV100796646; called by muse, mutect2, varscan2
- LRRIQ3 | c.1598T>C p.L533P | Missense Mutation (SNP) | VAF 29/160 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.033); catalogued as COSV100599588; called by muse, mutect2, varscan2
- LRRK2 | c.2405G>T p.S802I | Missense Mutation (SNP) | VAF 58/116 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as COSV100111418; called by muse, mutect2, varscan2
- LZTFL1 | c.188C>A p.A63D | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.106); catalogued as COSV99944955; called by muse, mutect2, varscan2
- MAGEF1 | c.20G>C p.S7T | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.191); catalogued as COSV100511068; called by muse, mutect2, varscan2
- MAN1A1 | c.1792T>A p.Y598N | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.819); catalogued as COSV100870809; called by muse, mutect2, varscan2
- MAP1B | c.5900C>T p.P1967L | Missense Mutation (SNP) | VAF 43/71 reads (61%) | SIFT deleterious (0); PolyPhen benign (0.328); catalogued as COSV99703045; called by muse, mutect2, varscan2
- MARK1 | c.198A>G p.I66M | Missense Mutation (SNP) | VAF 44/103 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100857607; called by muse, mutect2, varscan2
- MED1 | c.302G>A p.C101Y | Missense Mutation (SNP) | VAF 84/201 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100328240; called by muse, mutect2, varscan2
- MEIOC | c.2140G>T p.D714Y | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100740318; called by muse, mutect2, varscan2
- MEPE | c.302G>T p.S101I | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT tolerated (0.1); PolyPhen benign (0.15); catalogued as COSV100735007; called by muse, mutect2, varscan2
- MPHOSPH10 | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 22/118 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.715); catalogued as rs771841391, COSV99731241, COSV99731360; called by muse, mutect2, varscan2
- MRPL22 | c.392G>A p.R131K | Missense Mutation (SNP) | VAF 43/72 reads (60%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99501835; called by muse, mutect2, varscan2
- MSX2 | c.650C>A p.P217H | Missense Mutation (SNP) | VAF 34/52 reads (65%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.998); catalogued as COSV99497011; called by muse, mutect2, varscan2
- MTCL1 | c.2275G>A p.E759K (on ENST00000306329 / NM_001378206.1; = p.E399K on NM_015210.4) | Missense Mutation (SNP) | VAF 26/44 reads (59%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.465); catalogued as COSV100095866; called by muse, mutect2, varscan2
- MTFMT | c.986T>C p.I329T | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.129); catalogued as rs1012613611, COSV99584586; called by muse, mutect2, varscan2
- MUC16 | c.40890del p.S13631Afs*59 | Frame Shift Del (DEL) | VAF 47/94 reads (50%) | catalogued as COSV66692533; called by pindel, varscan2
- MUC17 | c.4856G>A p.S1619N | Missense Mutation (SNP) | VAF 93/358 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs147244857, COSV100075529, COSV60301781; called by muse, mutect2, varscan2
- MUC3A | c.7524C>G p.D2508E | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT tolerated, low confidence (0.06); catalogued as rs1235135866, COSV100115606; called by muse, mutect2
- MYO18B | c.4562G>C p.R1521P | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100125565; called by muse, mutect2, varscan2
- MYO1G | c.10G>T p.E4* | Nonsense Mutation (SNP) | VAF 15/78 reads (19%) | catalogued as COSV99349226; called by muse, mutect2, varscan2
- MYO5A | c.1309G>C p.D437H | Missense Mutation (SNP) | VAF 41/66 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100698278, COSV62563133; called by muse, mutect2, varscan2
- MYSM1 | c.1159C>G p.Q387E | Missense Mutation (SNP) | VAF 24/115 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.109); catalogued as COSV101284080; called by muse, mutect2, varscan2
- NAA15 | c.2326G>T p.D776Y | Missense Mutation (SNP) | VAF 88/151 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs1435031733, COSV99650002; called by muse, mutect2, varscan2
- NCAM2 | c.1720G>T p.G574* | Nonsense Mutation (SNP) | VAF 20/42 reads (48%) | catalogued as COSV99525901; called by muse, mutect2, varscan2
- NCR1 | c.811T>C p.W271R | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.622); catalogued as COSV99401242; called by muse, mutect2, varscan2
- NME8 | c.1657C>G p.R553G | Missense Mutation (SNP) | VAF 47/129 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52250845, COSV52253458; called by muse, mutect2, varscan2
- NPHS1 | c.2121G>C p.W707C | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.785); catalogued as COSV100800352; called by muse, mutect2, varscan2
- NRXN1 | c.2845G>A p.G949R | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.993); catalogued as rs868833247, COSV100457476; called by muse, mutect2, varscan2
- NTRK3 | c.1028G>T p.R343L | Missense Mutation (SNP) | VAF 73/116 reads (63%) | SIFT tolerated (0.17); PolyPhen benign (0.01); catalogued as rs183806623, COSV100448367, COSV58112677, COSV58116202; called by muse, mutect2, varscan2
- NXPE4 | c.146C>A p.S49Y | Missense Mutation (SNP) | VAF 84/216 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.169); catalogued as COSV100970580, COSV100970593; called by muse, mutect2, varscan2
- NXPH1 | c.811G>T p.G271* | Nonsense Mutation (SNP) | VAF 13/29 reads (45%) | catalogued as COSV101339837; called by muse, mutect2, varscan2
- OPN1LW | c.848C>A p.P283H | Missense Mutation (SNP) | VAF 164/222 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100885078, COSV64049436; called by muse, mutect2, varscan2
- OR2T4 | c.491A>T p.Y164F | Missense Mutation (SNP) | VAF 93/286 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100822660; called by muse, mutect2, varscan2
- OR4A16 | c.895C>A p.L299I | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.049); catalogued as rs754130096, COSV100125450; called by muse, mutect2, varscan2
- OR4C13 | c.629T>C p.L210P | Missense Mutation (SNP) | VAF 70/279 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.078); catalogued as rs1453338191, COSV101634250; called by muse, mutect2, varscan2
- OR4C16 | c.449C>A p.S150Y | Missense Mutation (SNP) | VAF 41/178 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs749912465, COSV58941909; called by muse, mutect2, varscan2
- OR4C6 | c.604G>T p.G202W | Missense Mutation (SNP) | VAF 57/148 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100051916; called by muse, mutect2, varscan2
- OR4D5 | c.800T>A p.M267K | Missense Mutation (SNP) | VAF 31/243 reads (13%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.628); catalogued as COSV100190243; called by muse, mutect2, varscan2
- OR4F6 | c.264G>T p.K88N | Missense Mutation (SNP) | VAF 181/262 reads (69%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.033); catalogued as COSV100187028; called by muse, mutect2, varscan2
- OR4K15 | c.346A>C p.I116L (on ENST00000305051; = p.I92L on NM_001005486.1) | Missense Mutation (SNP) | VAF 97/152 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as COSV100521188; called by muse, mutect2, varscan2
- OR5D18 | c.464C>A p.S155* | Nonsense Mutation (SNP) | VAF 50/227 reads (22%) | catalogued as rs1239546567, COSV100450946; called by muse, mutect2, varscan2
- OR5H15 | c.40C>G p.L14V | Missense Mutation (SNP) | VAF 109/527 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100736796, COSV62947330; called by muse, mutect2, varscan2
- OR5M3 | c.640A>G p.I214V | Missense Mutation (SNP) | VAF 26/137 reads (19%) | SIFT tolerated (0.53); PolyPhen benign (0.007); catalogued as rs1225381810, COSV100392722; called by muse, mutect2, varscan2
- OR5T2 | c.174C>A p.D58E | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.026); catalogued as COSV100507125, COSV57591608; called by muse, mutect2, varscan2
- OR6C76 | c.438G>A p.W146* | Nonsense Mutation (SNP) | VAF 87/232 reads (38%) | catalogued as COSV100094399, COSV60389232; called by muse, mutect2, varscan2
- OR8H2 | c.160C>T p.L54F | Missense Mutation (SNP) | VAF 47/374 reads (13%) | SIFT tolerated (0.71); PolyPhen benign (0.359); catalogued as COSV100542530; called by muse, mutect2, varscan2
- OR8I2 | c.428G>T p.W143L | Missense Mutation (SNP) | VAF 75/160 reads (47%) | SIFT tolerated (0.8); PolyPhen benign (0.009); catalogued as rs1384519032, COSV99042970; called by muse, mutect2, varscan2
- OR9I1 | c.478A>T p.T160S | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100110686; called by muse, mutect2, varscan2
- OTOGL | c.4729T>A p.C1577S (on ENST00000547103; = p.C1568S on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 36/83 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100088068; called by muse, mutect2, varscan2
- OTX2 | c.32C>A p.A11E | Missense Mutation (SNP) | VAF 13/19 reads (68%) | SIFT deleterious (0.01); PolyPhen benign (0.131); catalogued as COSV100258122; called by muse, mutect2, varscan2
- OXR1 | c.1165A>T p.T389S (on ENST00000442977 / NM_001198532.1; = p.T388S on NM_018002.3) | Missense Mutation (SNP) | VAF 95/122 reads (78%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV100367835; called by muse, mutect2, varscan2
- P3H3 | c.1526G>C p.R509P | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.702); catalogued as COSV99300789, COSV99301809; called by muse, mutect2, varscan2
- PACS1 | c.2769G>A p.M923I | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV100270758; called by muse, mutect2, varscan2
- PAGE3 | c.284T>C p.L95P | Missense Mutation (SNP) | VAF 33/42 reads (79%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.565); catalogued as COSV100892027; called by muse, mutect2, varscan2
- PANX2 | c.1864A>T p.T622S | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.005); catalogued as COSV99348347, COSV99348745; called by mutect2, varscan2
- PAPLN | c.796G>A p.E266K (on ENST00000554301; = p.E239K on NM_173462.4) | Missense Mutation (SNP) | VAF 21/28 reads (75%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as COSV99390590; called by muse, mutect2, varscan2
- PASK | c.1615G>A p.D539N | Missense Mutation (SNP) | VAF 114/311 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.116); catalogued as rs754913621, COSV99300441; called by muse, mutect2, varscan2
- PCDH12 | c.2803C>A p.L935M | Missense Mutation (SNP) | VAF 31/58 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99191750; called by muse, mutect2, varscan2
- PCDH12 | c.2802C>A p.S934R | Missense Mutation (SNP) | VAF 31/57 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as COSV51521662, COSV99191754; called by muse, mutect2, varscan2
- PCDH15 | c.3575A>T p.K1192I | Missense Mutation (SNP) | VAF 60/92 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100229157; called by muse, mutect2, varscan2
- PCDH9 | c.79A>T p.I27F | Missense Mutation (SNP) | VAF 56/93 reads (60%) | SIFT tolerated (0.72); PolyPhen probably damaging (0.916); catalogued as COSV60547295; called by muse, mutect2, varscan2
- PCDHB11 | c.1507C>A p.L503M | Missense Mutation (SNP) | VAF 95/159 reads (60%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100697215; called by muse, mutect2, varscan2
- PCDHB11 | c.2159C>A p.A720D | Missense Mutation (SNP) | VAF 96/172 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.655); catalogued as COSV100697216; called by muse, mutect2, varscan2
- PCDHB13 | c.1595G>C p.G532A | Missense Mutation (SNP) | VAF 46/84 reads (55%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.12); catalogued as COSV99507994; called by muse, mutect2, varscan2
- PCDHGA9 | c.549G>T p.Q183H | Missense Mutation (SNP) | VAF 37/67 reads (55%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.16); catalogued as COSV99532167; called by muse, mutect2, varscan2
- PCSK4 | c.214C>T p.H72Y | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs1038527116; called by muse, mutect2, varscan2
- PDE3A | c.1009C>A p.Q337K | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.056); catalogued as COSV100762959; called by muse, mutect2, varscan2
- PDYN | c.137C>A p.S46Y | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV99453445; called by muse, mutect2, varscan2
- PEX5L | c.148C>T p.P50S | Missense Mutation (SNP) | VAF 344/452 reads (76%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV99830243; called by muse, mutect2, varscan2
- PHF20L1 | c.1123A>C p.I375L | Missense Mutation (SNP) | VAF 337/403 reads (84%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV99622359; called by muse, mutect2, varscan2
- PKHD1 | c.8501A>T p.E2834V | Missense Mutation (SNP) | VAF 42/165 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as COSV100584918; called by muse, mutect2, varscan2
- PKHD1 | c.249C>G p.F83L | Missense Mutation (SNP) | VAF 57/243 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.294); catalogued as COSV61884855; called by muse, mutect2, varscan2
- PKN2 | c.1054A>G p.T352A | Missense Mutation (SNP) | VAF 62/146 reads (42%) | SIFT tolerated (0.88); PolyPhen benign (0.001); catalogued as COSV100281847; called by muse, mutect2, varscan2
- PLCXD3 | c.475G>T p.V159F | Missense Mutation (SNP) | VAF 77/323 reads (24%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.988); catalogued as rs1178597786, COSV100126584; called by muse, mutect2, varscan2
- PLEKHA7 | c.620G>C p.G207A | Missense Mutation (SNP) | VAF 53/82 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100850529, COSV63048861; called by muse, mutect2, varscan2
- PLEKHS1 | c.4G>T p.E2* | Nonsense Mutation (SNP) | VAF 32/53 reads (60%) | catalogued as COSV100733019; called by muse, mutect2, varscan2
- PLSCR4 | c.448G>T p.D150Y | Missense Mutation (SNP) | VAF 34/83 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); catalogued as COSV100724401; called by muse, mutect2, varscan2
- POLD1 | c.1331G>T p.R444L | Missense Mutation (SNP) | VAF 38/66 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV101486939; called by muse, mutect2, varscan2
- POM121L12 | c.356G>T p.C119F | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.118); catalogued as COSV101375004; called by muse, mutect2, varscan2
- PPP1R3A | c.644T>C p.V215A | Missense Mutation (SNP) | VAF 31/140 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.052); catalogued as rs1259992749, COSV99494698; called by muse, mutect2, varscan2
- PRKCE | c.483G>T p.R161S | Missense Mutation (SNP) | VAF 49/116 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.41); catalogued as COSV100079819, COSV60331329; called by muse, mutect2, varscan2
- PRRC2B | c.1062T>A p.N354K | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100622377; called by muse, mutect2, varscan2
- PSG7 | c.837C>A p.S279R | Missense Mutation (SNP) | VAF 209/361 reads (58%) | SIFT tolerated (0.35); PolyPhen benign (0.073); catalogued as COSV101343360; called by muse, mutect2, varscan2
- PTK2 | c.1306G>A p.V436I | Missense Mutation (SNP) | VAF 110/156 reads (71%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV100571345; called by muse, mutect2, varscan2
- PTPN13 | c.3594C>G p.N1198K (on ENST00000411767 / NM_080683.3; = p.N1179K on NM_006264.3) | Missense Mutation (SNP) | VAF 29/117 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0.034); catalogued as COSV100365596; called by muse, mutect2, varscan2
- PTPRN2 | c.2856C>A p.S952R | Missense Mutation (SNP) | VAF 47/97 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101235519; called by muse, mutect2, varscan2
- PTPRZ1 | c.3953C>G p.S1318* | Nonsense Mutation (SNP) | VAF 43/92 reads (47%) | catalogued as COSV101100940; called by muse, mutect2, varscan2
- PUS10 | c.1121A>G p.K374R | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT tolerated (0.41); PolyPhen benign (0.02); catalogued as COSV100369880; called by muse, mutect2, varscan2
- PYM1 | c.71G>T p.G24V | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100212723; called by muse, mutect2, varscan2
- RBAK | c.1663A>T p.T555S | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.474); catalogued as COSV100806802; called by muse, mutect2, varscan2
- RELN | c.260T>A p.L87* | Nonsense Mutation (SNP) | VAF 97/190 reads (51%) | catalogued as COSV100635140; called by muse, mutect2, varscan2
- RGS21 | c.319T>A p.C107S | Missense Mutation (SNP) | VAF 58/172 reads (34%) | SIFT tolerated (0.38); PolyPhen benign (0.049); catalogued as COSV101314104; called by muse, mutect2, varscan2
- RIPOR2 | c.360G>C p.K120N | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99430363; called by muse, mutect2
- RNF213 | c.6101G>A p.R2034Q | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs918889499, COSV60407638; called by muse, mutect2, varscan2
- RNF217 | c.1009G>T p.G337C (on ENST00000521654 / NM_001286398.2; = p.G45C on NM_152553.5) | Missense Mutation (SNP) | VAF 46/113 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV99255402; called by muse, mutect2, varscan2
- RNF217 | c.1423A>T p.K475* (on ENST00000521654 / NM_001286398.2; = p.K183* on NM_152553.5) | Nonsense Mutation (SNP) | VAF 40/188 reads (21%) | catalogued as COSV99255404; called by muse, mutect2, varscan2
- ROBO2 | c.1919G>T p.R640L | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.463); catalogued as COSV100170592, COSV59931373; called by muse, mutect2, varscan2
- RTN1 | c.619C>T p.H207Y | Missense Mutation (SNP) | VAF 123/192 reads (64%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99957141; called by muse, mutect2, varscan2
- RYR2 | c.1268T>C p.V423A | Missense Mutation (SNP) | VAF 29/185 reads (16%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as COSV100773299; called by muse, mutect2, varscan2
- RYR2 | c.7037C>A p.A2346E | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV63678310; called by muse, mutect2, varscan2
- RYR2 | c.8707G>C p.V2903L | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated (0.26); PolyPhen benign (0.014); catalogued as COSV100773301, COSV63690624; called by muse, mutect2, varscan2
- RYR2 | c.9054G>C p.R3018S | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.505); catalogued as COSV63672280, COSV63698656; called by muse, mutect2
- RYR2 | c.9586A>T p.S3196C | Missense Mutation (SNP) | VAF 51/171 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.371); catalogued as COSV100773304; called by muse, varscan2
- RYR2 | c.9676A>T p.I3226F | Missense Mutation (SNP) | VAF 60/167 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.021); catalogued as COSV100773306; called by muse, varscan2
- SCAF11 | c.3629C>T p.P1210L | Missense Mutation (SNP) | VAF 36/111 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.387); catalogued as rs1195318858, COSV101014746; called by muse, mutect2, varscan2
- SCG3 | c.107T>G p.L36* | Nonsense Mutation (SNP) | VAF 62/100 reads (62%) | catalogued as COSV55020724, COSV99591311; called by muse, mutect2, varscan2
- SCN1A | c.3254G>T p.G1085V (on ENST00000303395 / NM_001202435.3; = p.G1074V on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 50/120 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.173); catalogued as COSV57679594; called by muse, mutect2, varscan2
- SCN7A | c.680T>C p.V227A | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.698); catalogued as COSV101313389; called by muse, mutect2
- SEC23B | c.1837G>T p.D613Y | Missense Mutation (SNP) | VAF 35/131 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as COSV99358190; called by muse, mutect2, varscan2
- SEMA6B | c.1579C>A p.Q527K | Missense Mutation (SNP) | VAF 15/24 reads (63%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.81); catalogued as COSV100015236; called by muse, mutect2, varscan2
- SEMA6B | c.1578C>A p.C526* | Nonsense Mutation (SNP) | VAF 15/24 reads (63%) | catalogued as COSV100015237; called by muse, mutect2, varscan2
- SERPIND1 | c.244C>A p.L82M | Missense Mutation (SNP) | VAF 169/219 reads (77%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.885); catalogued as COSV99300544; called by muse, mutect2, varscan2
- SETDB1 | c.975A>T p.E325D | Missense Mutation (SNP) | VAF 39/89 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.027); catalogued as COSV99646049; called by muse, mutect2, varscan2
- SIRT4 | c.685C>G p.P229A | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99177490; called by muse, mutect2, varscan2
- SLC12A3 | c.1070G>T p.G357V | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99344907; called by muse, mutect2, varscan2
- SLC17A4 | c.206C>T p.A69V | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0.033); catalogued as rs1278921179, COSV64955460; called by muse, mutect2
- SLC27A6 | c.1831C>G p.Q611E | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.028); catalogued as rs1216848624, COSV99323668; called by muse, mutect2, varscan2
- SLC35F6 | c.839G>A p.G280D | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100733768; called by muse, mutect2, varscan2
- SLC4A8 | c.2467C>A p.L823M | Missense Mutation (SNP) | VAF 67/166 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100177706; called by muse, mutect2, varscan2
- SLC9A8 | c.334C>G p.L112V | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT tolerated (0.25); PolyPhen benign (0.044); catalogued as rs1199214508, COSV100846356; called by muse, mutect2, varscan2
- SP3 | c.470G>T p.G157V | Missense Mutation (SNP) | VAF 123/303 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.155); catalogued as COSV100022285; called by muse, mutect2, varscan2
- SPIDR | c.2362G>A p.E788K | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs550506526, COSV52395138; called by muse, mutect2
- SPTA1 | c.6743T>A p.L2248H | Missense Mutation (SNP) | VAF 66/192 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100935763; called by muse, mutect2, varscan2
- SPTA1 | c.4445G>A p.W1482* | Nonsense Mutation (SNP) | VAF 11/96 reads (11%) | catalogued as COSV100935764; called by muse, mutect2, varscan2
- SRGAP1 | c.2239G>A p.E747K | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as COSV100755223; called by muse, mutect2, varscan2
- SSUH2 | c.11C>A p.P4Q | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.127); catalogued as COSV100436213; called by muse, mutect2, varscan2
- ST6GALNAC3 | c.419C>G p.P140R | Missense Mutation (SNP) | VAF 57/143 reads (40%) | PolyPhen benign (0.088); catalogued as COSV100084767, COSV100085804; called by muse, mutect2, varscan2
- ST8SIA3 | c.522C>A p.S174R | Missense Mutation (SNP) | VAF 61/96 reads (64%) | PolyPhen probably damaging (0.999); catalogued as COSV100129744; called by muse, mutect2, varscan2
- ST8SIA6 | c.1061C>A p.P354H | Missense Mutation (SNP) | VAF 115/197 reads (58%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.866); catalogued as rs201378551, COSV101112240; called by muse, mutect2, varscan2
- STAR | c.571A>C p.K191Q | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT tolerated (0.42); PolyPhen benign (0.075); catalogued as COSV99379263; called by muse, mutect2, varscan2
- STAT2 | c.736T>G p.C246G | Missense Mutation (SNP) | VAF 31/100 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100029185; called by muse, mutect2, varscan2
- STAT3 | c.1888G>A p.G630S | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.575); catalogued as COSV99233391; called by muse, mutect2, varscan2
- STXBP1 | c.48T>G p.H16Q | Missense Mutation (SNP) | VAF 34/61 reads (56%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV100964648; called by muse, mutect2, varscan2
- STXBP5L | c.1567T>G p.C523G | Missense Mutation (SNP) | VAF 39/84 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99876856; called by muse, mutect2, varscan2
- SYN3 | c.397G>C p.A133P | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); catalogued as COSV100250165, COSV60508836; called by muse, mutect2, varscan2
- TADA1 | c.514G>C p.V172L | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.377); catalogued as rs1279668923, COSV100902387; called by muse, mutect2, varscan2
- TAF1A | c.365C>A p.A122D | Missense Mutation (SNP) | VAF 87/282 reads (31%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.943); catalogued as COSV100601120; called by muse, mutect2, varscan2
- TBC1D2B | c.2648C>G p.S883C | Missense Mutation (SNP) | VAF 10/12 reads (83%) | SIFT deleterious (0.02); PolyPhen benign (0.436); catalogued as COSV100317862; called by muse, mutect2, varscan2
- TBC1D32 | c.2957G>C p.C986S | Missense Mutation (SNP) | VAF 25/118 reads (21%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.893); catalogued as COSV99251611; called by muse, mutect2, varscan2
- TBX15 | c.1672C>A p.L558M (on ENST00000369429 / NM_001330677.2; = p.L452M on NM_152380.3) | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.999); catalogued as COSV99254935; called by muse, mutect2, varscan2
- TBX22 | c.1076G>A p.C359Y | Missense Mutation (SNP) | VAF 75/110 reads (68%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV100960983; called by muse, mutect2, varscan2
- TGFBRAP1 | c.1951T>G p.Y651D | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99305648; called by muse, mutect2, varscan2
- THUMPD2 | c.562G>A p.E188K | Missense Mutation (SNP) | VAF 38/89 reads (43%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV53187951; called by muse, mutect2, varscan2
- TMEM131 | c.4835G>T p.C1612F | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated, low confidence (0.79); PolyPhen benign (0); catalogued as COSV99489959; called by muse, mutect2, varscan2
- TMEM139 | c.387C>G p.S129R | Missense Mutation (SNP) | VAF 7/121 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV100131324; called by muse, mutect2
- TMEM147 | c.462G>C p.W154C | Missense Mutation (SNP) | VAF 48/71 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99383197; called by muse, mutect2, varscan2
- TMEM214 | c.2009G>A p.C670Y | Missense Mutation (SNP) | VAF 41/86 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99476592; called by muse, mutect2, varscan2
- TMEM234 | c.89C>A p.A30D | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT tolerated (0.51); PolyPhen benign (0.216); catalogued as COSV100557343; called by muse, mutect2, varscan2
- TMEM94 | c.3919C>G p.L1307V | Missense Mutation (SNP) | VAF 35/71 reads (49%) | SIFT tolerated (0.15); PolyPhen benign (0.171); catalogued as COSV100051083; called by muse, mutect2, varscan2
- TMPO | c.1289C>T p.P430L | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.203); catalogued as COSV99701913, COSV99702257; called by muse, mutect2, varscan2
- TMTC2 | c.391G>T p.E131* | Nonsense Mutation (SNP) | VAF 53/114 reads (46%) | catalogued as COSV100339018; called by muse, mutect2, varscan2
- TNFAIP3 | c.751G>T p.G251C | Missense Mutation (SNP) | VAF 35/80 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99397348; called by muse, mutect2, varscan2
- TNFSF8 | c.664G>T p.E222* | Nonsense Mutation (SNP) | VAF 89/131 reads (68%) | catalogued as COSV99802174; called by muse, mutect2, varscan2
- TOP3A | c.2173C>A p.L725I | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV100329367; called by muse, mutect2, varscan2
- TPH2 | c.851C>A p.P284Q | Missense Mutation (SNP) | VAF 24/158 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV100422458; called by muse, mutect2, varscan2
- TRIM25 | c.1374A>T p.K458N | Missense Mutation (SNP) | VAF 51/119 reads (43%) | SIFT tolerated (0.46); PolyPhen benign (0.005); catalogued as COSV100381245; called by muse, mutect2, varscan2
- TRIM27 | c.1334G>T p.G445V | Missense Mutation (SNP) | VAF 53/90 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101019518; called by muse, mutect2, varscan2
- TRPC3 | c.2617A>T p.N873Y (on ENST00000379645 / NM_001366479.2; = p.N800Y on NM_003305.2) | Missense Mutation (SNP) | VAF 23/38 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99313642; called by muse, mutect2, varscan2
- TRPS1 | c.3193G>T p.G1065C (on ENST00000220888 / NM_001330599.2; = p.G1078C on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 200/245 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99635333; called by muse, mutect2, varscan2
- TUBB2A | c.179T>G p.V60G | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100373968; called by muse, mutect2, varscan2
- TUBB6 | c.85G>C p.G29R | Missense Mutation (SNP) | VAF 41/68 reads (60%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV100481245; called by muse, mutect2, varscan2
- TYR | c.571G>T p.G191* | Nonsense Mutation (SNP) | VAF 173/360 reads (48%) | catalogued as COSV54473376, COSV99635633; called by muse, mutect2
- U2SURP | c.3044G>C p.R1015T | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.8); PolyPhen possibly damaging (0.879); catalogued as COSV101204606; called by muse, mutect2, varscan2
- UNC45B | c.1698C>T p.T566= | Splice Region (SNP) | VAF 13/81 reads (16%) | catalogued as rs933404553, COSV52102721; called by muse, mutect2, varscan2
- UNC5D | c.1964C>A p.T655K | Missense Mutation (SNP) | VAF 26/184 reads (14%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.994); catalogued as COSV99779570; called by muse, mutect2, varscan2
- USH2A | c.9412G>A p.G3138S | Missense Mutation (SNP) | VAF 60/159 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100244047; called by muse, mutect2, varscan2
- USP34 | c.1726A>T p.S576C | Missense Mutation (SNP) | VAF 92/184 reads (50%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.753); catalogued as COSV101277298, COSV68404102; called by muse, mutect2, varscan2
- USP45 | c.2135C>A p.A712E | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100570009; called by muse, mutect2, varscan2
- USP46 | c.308T>C p.I103T | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV101484326; called by muse, mutect2, varscan2
- USP9X | c.3067C>G p.Q1023E | Missense Mutation (SNP) | VAF 63/87 reads (72%) | SIFT tolerated (0.16); PolyPhen benign (0.037); catalogued as COSV100200274; called by muse, mutect2, varscan2
- UTP18 | c.1405A>G p.I469V | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT tolerated (0.4); PolyPhen benign (0.023); catalogued as rs1295989341, COSV99834613; called by muse, mutect2, varscan2
- UTRN | c.1342C>T p.P448S | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as rs545375734, COSV100840753; called by muse, mutect2
- UTRN | c.3109G>A p.D1037N | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.816); catalogued as COSV100839783, COSV100840754; called by muse, mutect2, varscan2
- UTRN | c.7424G>T p.R2475L | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.378); catalogued as COSV100840755; called by muse, mutect2, varscan2
- VNN1 | c.937G>T p.V313L | Missense Mutation (SNP) | VAF 43/82 reads (52%) | SIFT tolerated (0.12); PolyPhen benign (0.045); catalogued as COSV100907875; called by muse, mutect2, varscan2
- VPS13B | c.7904G>C p.C2635S | Missense Mutation (SNP) | VAF 58/394 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100663994, COSV62148482; called by muse, mutect2, varscan2
- VPS13C | c.3395T>C p.I1132T (on ENST00000644861 / NM_020821.3; = p.I1089T on NM_017684.5) | Missense Mutation (SNP) | VAF 40/63 reads (63%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.621); catalogued as COSV99830614; called by muse, mutect2, varscan2
- VPS13D | c.10792A>G p.T3598A | Missense Mutation (SNP) | VAF 38/127 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.092); catalogued as COSV99170071; called by muse, mutect2, varscan2
- WDR36 | c.1116G>C p.L372F | Missense Mutation (SNP) | VAF 55/115 reads (48%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as COSV101540839; called by muse, mutect2, varscan2
- WDR62 | c.390+1G>T p.X130_splice | Splice Site (SNP) | VAF 87/134 reads (65%) | catalogued as rs1284984423, COSV99544390; called by muse, mutect2, varscan2
- WWP1 | c.2143A>G p.I715V | Missense Mutation (SNP) | VAF 38/55 reads (69%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as COSV99617444; called by muse, mutect2, varscan2
- XIRP2 | c.3113G>T p.S1038I (on ENST00000628543; = p.S1213I on NM_152381.6) | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as COSV99748801; called by muse, mutect2, varscan2
- YKT6 | c.370G>C p.D124H | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.587); catalogued as COSV99034218, COSV99790734; called by muse, mutect2, varscan2
- ZAP70 | c.521A>T p.E174V | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99386055; called by muse, mutect2, varscan2
- ZFAT | c.1321G>T p.A441S | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.545); catalogued as COSV100914746, COSV100915152; called by muse, mutect2, varscan2
- ZFYVE28 | c.527T>A p.V176D | Missense Mutation (SNP) | VAF 20/25 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV99343859; called by muse, mutect2, varscan2
- ZIC1 | c.788G>T p.G263V | Missense Mutation (SNP) | VAF 30/141 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99292583; called by muse, mutect2, varscan2
- ZNF230 | c.573G>C p.L191F | Missense Mutation (SNP) | VAF 63/108 reads (58%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.548); catalogued as COSV101432176; called by muse, mutect2, varscan2
- ZNF25 | c.113T>A p.L38Q | Missense Mutation (SNP) | VAF 40/73 reads (55%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as COSV100224834; called by muse, mutect2, varscan2
- ZNF416 | c.1543A>G p.I515V | Missense Mutation (SNP) | VAF 36/129 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.08); catalogued as COSV99544009; called by muse, mutect2, varscan2
- ZNF429 | c.1765G>A p.G589R | Missense Mutation (SNP) | VAF 48/75 reads (64%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV100642060, COSV100642064; called by muse, mutect2, varscan2
- ZNF521 | c.479G>T p.S160I | Missense Mutation (SNP) | VAF 57/124 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100833606, COSV64124717; called by muse, mutect2, varscan2
- ZNF586 | c.107A>T p.Q36L | Missense Mutation (SNP) | VAF 125/210 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.498); catalogued as COSV101197766; called by muse, mutect2, varscan2
- ZNF749 | c.141A>T p.V47= | Splice Region (SNP) | VAF 62/97 reads (64%) | catalogued as COSV100494525; called by muse, mutect2, varscan2
- ZNF80 | c.736G>T p.E246* | Nonsense Mutation (SNP) | VAF 51/156 reads (33%) | catalogued as COSV100352193; called by muse, mutect2, varscan2
- ZNF804A | c.1149C>A p.N383K | Missense Mutation (SNP) | VAF 39/114 reads (34%) | SIFT tolerated (0.26); PolyPhen benign (0.01); catalogued as COSV100170698, COSV56446669; called by muse, mutect2, varscan2
- ZNF804A | c.1657T>G p.C553G | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.163); catalogued as COSV100170699; called by muse, mutect2, varscan2
- ZNF804B | c.1124A>G p.H375R | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.454); catalogued as COSV100306897; called by muse, mutect2, varscan2
- ZNF98 | c.1354C>A p.H452N | Missense Mutation (SNP) | VAF 44/86 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100757674, COSV63339184; called by muse, mutect2, varscan2
- ARID1A | c.3524del p.P1175Hfs*5 | Frame Shift Del (DEL) | VAF 36/67 reads (54%) | called by mutect2, pindel, varscan2
- ATP8B1 | c.70del p.Y24Tfs*57 | Frame Shift Del (DEL) | VAF 85/169 reads (50%) | called by mutect2, pindel, varscan2
- CNTNAP2 | c.1348+1del | Frame Shift Del (DEL) | VAF 28/77 reads (36%) | called by mutect2, pindel, varscan2
- DPP10 | c.1035_1071del p.L346Kfs*5 | Frame Shift Del (DEL) | VAF 10/59 reads (17%) | called by mutect2, pindel
- FAT2 | c.2351_2367delinsTA p.N784_N789delinsI | In Frame Del (DEL) | VAF 10/50 reads (20%) | called by pindel, varscan2*
- FCGBP | c.1648G>A p.V550I | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT tolerated (0.12); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- FOXD4L4 | c.65G>T p.G22V | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.483); called by mutect2, varscan2
- FRG2C | c.78G>T p.Q26H | Missense Mutation (SNP) | VAF 35/196 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.176); called by muse, mutect2, varscan2
- GPR179 | c.5447C>G p.A1816G (on ENST00000621958; = p.A1815G on NM_001004334.4) | Missense Mutation (SNP) | VAF 55/205 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- HYAL4 | c.287del p.G96Dfs*21 | Frame Shift Del (DEL) | VAF 41/108 reads (38%) | called by mutect2, pindel, varscan2
- IGKV3D-20 | c.121C>A p.L41I | Missense Mutation (SNP) | VAF 49/111 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- IGLV2-18 | c.185G>T p.G62V | Missense Mutation (SNP) | VAF 118/1165 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- NIPAL3 | c.816dup p.A273Cfs*51 | Frame Shift Ins (INS) | VAF 51/101 reads (50%) | called by mutect2, pindel, varscan2
- OR4A15 | c.664del p.S222Lfs*48 | Frame Shift Del (DEL) | VAF 25/133 reads (19%) | called by mutect2, pindel, varscan2
- OR8G2P | c.177G>T p.M59I | Missense Mutation (SNP) | VAF 96/386 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- PAX8 | c.942del p.S315Pfs*111 | Frame Shift Del (DEL) | VAF 9/46 reads (20%) | called by mutect2, pindel, varscan2
- PRAMEF4 | c.800T>G p.L267R | Missense Mutation (SNP) | VAF 52/587 reads (9%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); called by muse, mutect2
- PTEN | c.62del p.F21Sfs*3 | Frame Shift Del (DEL) | VAF 50/94 reads (53%) | called by mutect2, pindel, varscan2
- RASL12 | c.284dup p.V96Gfs*12 | Frame Shift Ins (INS) | VAF 22/51 reads (43%) | called by mutect2, pindel, varscan2
- SUN1 | c.1329dup p.P444Afs*17 (on ENST00000405266 / NM_001367651.1; = p.P324Afs*17 on NM_025154.6 and 13 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 26/59 reads (44%) | called by mutect2, pindel, varscan2
- TMPO | c.1280dup p.L427Ffs*18 | Frame Shift Ins (INS) | VAF 30/122 reads (25%) | called by mutect2, varscan2
- ABCA8 | c.4452A>G p.Q1484= | Silent (SNP) | VAF 25/90 reads (28%) | catalogued as rs143569370; called by muse, mutect2, varscan2
- ABCF1 | c.2202C>T p.H734= (on ENST00000326195 / NM_001025091.2; = p.H696= on NM_001090.3) | Silent (SNP) | VAF 94/168 reads (56%) | catalogued as rs373981483; called by muse, mutect2, varscan2
- ACTL6A | c.936C>G p.S312= | Silent (SNP) | VAF 70/400 reads (18%) | catalogued as COSV101199760; called by muse, mutect2, varscan2
- ADGRD1 | c.1212G>T p.G404= | Silent (SNP) | VAF 21/54 reads (39%) | catalogued as rs919480708, COSV55453014, COSV99897483; called by muse, mutect2, varscan2
- ATRNL1 | c.3414A>G p.E1138= | Silent (SNP) | VAF 49/71 reads (69%) | catalogued as rs1554969779, COSV100373191; called by muse, mutect2, varscan2
- BAK1 | c.474G>T p.V158= | Silent (SNP) | VAF 22/45 reads (49%) | catalogued as COSV100645904; called by muse, mutect2, varscan2
- BCLAF1 | c.393G>C p.R131= | Silent (SNP) | VAF 32/212 reads (15%) | catalogued as rs139735050, COSV100786695, COSV100787138; called by muse, varscan2
- BMPER | c.468G>T p.L156= | Silent (SNP) | VAF 46/110 reads (42%) | catalogued as COSV51821529, COSV99780803; called by muse, mutect2, varscan2
- BSX | c.384G>A p.R128= | Silent (SNP) | VAF 93/279 reads (33%) | catalogued as COSV100545382; called by muse, mutect2, varscan2
- CC2D1B | c.2010C>A p.A670= | Silent (SNP) | VAF 73/147 reads (50%) | catalogued as COSV99430435; called by muse, mutect2, varscan2
- CDK19 | c.1393C>T p.L465= | Silent (SNP) | VAF 33/67 reads (49%) | catalogued as COSV100099522; called by muse, mutect2, varscan2
- CNGA1 | c.948T>A p.S316= | Silent (SNP) | VAF 48/77 reads (62%) | catalogued as COSV100652374; called by muse, mutect2, varscan2
- CNTNAP2 | c.3303C>T p.D1101= | Silent (SNP) | VAF 18/93 reads (19%) | catalogued as rs772181075, COSV62161835; called by muse, mutect2, varscan2
- CPS1 | c.480A>T p.A160= | Silent (SNP) | VAF 46/143 reads (32%) | catalogued as COSV99244411; called by muse, mutect2, varscan2
- CPXCR1 | c.726A>T p.I242= | Silent (SNP) | VAF 14/17 reads (82%) | catalogued as COSV99342484; called by muse, mutect2, varscan2
- CUX2 | c.2277C>G p.L759= | Silent (SNP) | VAF 14/36 reads (39%) | catalogued as rs1313395324, COSV99921034; called by muse, mutect2, varscan2
- DCDC1 | c.2769G>A p.K923= (on ENST00000597505 / NM_001367979.1; = p.K30= on NM_020869.3) | Silent (SNP) | VAF 17/28 reads (61%) | catalogued as COSV100338898; called by muse, mutect2, varscan2
- DENND1B | c.168C>T p.D56= | Silent (SNP) | VAF 23/62 reads (37%) | catalogued as rs373887056; called by muse, mutect2, varscan2
- DHX57 | c.1845A>G p.K615= | Silent (SNP) | VAF 257/544 reads (47%) | catalogued as COSV99770050; called by muse, mutect2, varscan2
- DNAH11 | c.12081A>T p.T4027= | Silent (SNP) | VAF 31/69 reads (45%) | catalogued as COSV100181391; called by muse, mutect2, varscan2
- DPEP3 | c.1368C>A p.T456= | Silent (SNP) | VAF 14/32 reads (44%) | catalogued as rs774838533, COSV52053502; called by muse, mutect2, varscan2
- DPP3 | c.129C>T p.Y43= | Silent (SNP) | VAF 31/62 reads (50%) | catalogued as rs200614411, COSV57856107; called by muse, mutect2, varscan2
- DRC7 | c.366G>A p.E122= | Silent (SNP) | VAF 39/171 reads (23%) | catalogued as COSV61053810; called by muse, mutect2, varscan2
- DSG3 | c.1650C>A p.L550= | Silent (SNP) | VAF 73/127 reads (57%) | catalogued as COSV99934874; called by muse, mutect2, varscan2
- EFNB2 | c.783G>T p.P261= | Silent (SNP) | VAF 33/60 reads (55%) | catalogued as COSV99809012; called by muse, mutect2, varscan2
- ERICH3 | c.2766G>C p.L922= | Silent (SNP) | VAF 89/183 reads (49%) | catalogued as COSV100446083, COSV58611104; called by muse, mutect2, varscan2
- ERICH6 | c.600T>C p.S200= | Silent (SNP) | VAF 68/204 reads (33%) | catalogued as COSV99902121; called by muse, mutect2, varscan2
- FCRL4 | c.891G>T p.G297= | Silent (SNP) | VAF 35/100 reads (35%) | catalogued as COSV99620609; called by muse, mutect2, varscan2
- FRG2C | c.645G>T p.R215= | Silent (SNP) | VAF 31/181 reads (17%) | catalogued as rs1392460052; called by muse, mutect2, varscan2
- GAL3ST1 | c.930C>T p.H310= | Silent (SNP) | VAF 13/30 reads (43%) | catalogued as COSV100143282; called by muse, mutect2, varscan2
- GLI3 | c.3567C>T p.R1189= | Silent (SNP) | VAF 72/185 reads (39%) | catalogued as COSV67886629; called by muse, mutect2, varscan2
- HDAC9 | c.2121G>T p.L707= | Silent (SNP) | VAF 8/47 reads (17%) | catalogued as COSV101287962; called by muse, mutect2, varscan2
- HECTD4 | c.6777A>T p.S2259= | Silent (SNP) | VAF 16/72 reads (22%) | catalogued as COSV101108429; called by muse, mutect2, varscan2
- HYAL4 | c.1158G>A p.R386= | Silent (SNP) | VAF 17/97 reads (18%) | catalogued as rs1375042418, COSV99772537; called by muse, mutect2, varscan2
- IFNL2 | c.354C>A p.A118= | Silent (SNP) | VAF 34/53 reads (64%) | catalogued as COSV100122141; called by muse, mutect2, varscan2
- IGF2BP1 | c.1659C>A p.I553= | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as COSV99289227; called by muse, mutect2, varscan2
- IQGAP3 | c.3435A>T p.R1145= | Silent (SNP) | VAF 61/147 reads (41%) | catalogued as COSV100752463; called by muse, mutect2, varscan2
- ISM1 | c.666C>T p.D222= | Silent (SNP) | VAF 20/79 reads (25%) | catalogued as COSV99340417; called by muse, mutect2, varscan2
- KCNC2 | c.1065C>T p.I355= | Silent (SNP) | VAF 15/91 reads (16%) | catalogued as rs1327196529, COSV100130117; called by muse, mutect2, varscan2
- KIAA0100 | c.6588A>G p.E2196= | Silent (SNP) | VAF 57/142 reads (40%) | catalogued as COSV99972365; called by muse, mutect2, varscan2
- LHCGR | c.633G>A p.E211= | Silent (SNP) | VAF 61/119 reads (51%) | catalogued as COSV99684358; called by muse, mutect2, varscan2
- LRP1B | c.7926G>A p.G2642= | Silent (SNP) | VAF 11/72 reads (15%) | catalogued as COSV101262162; called by muse, mutect2, varscan2
- LRRC40 | c.99G>A p.K33= | Silent (SNP) | VAF 46/96 reads (48%) | catalogued as COSV100918396; called by muse, mutect2, varscan2
- LRRN2 | c.2115G>A p.L705= | Silent (SNP) | VAF 31/245 reads (13%) | catalogued as rs1365906952, COSV100913012; called by muse, mutect2, varscan2
- MYO7B | c.3048C>G p.V1016= | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as COSV101268431; called by muse, mutect2
- MYO7B | c.4177C>A p.R1393= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV67344671; called by muse, mutect2
- NAV3 | c.966C>G p.A322= | Silent (SNP) | VAF 11/55 reads (20%) | catalogued as rs200037827, COSV99896744; called by muse, mutect2, varscan2
- NEB | c.8682C>T p.S2894= | Silent (SNP) | VAF 53/122 reads (43%) | catalogued as rs373799650; called by muse, mutect2, varscan2
- NINL | c.2238G>T p.S746= | Silent (SNP) | VAF 13/34 reads (38%) | catalogued as COSV54002658, COSV99626602; called by muse, mutect2, varscan2
- NTSR1 | c.426C>A p.R142= | Silent (SNP) | VAF 26/64 reads (41%) | catalogued as COSV100980736, COSV65139714; called by muse, mutect2, varscan2
- NUP205 | c.5103A>G p.L1701= | Silent (SNP) | VAF 61/275 reads (22%) | catalogued as COSV99607751; called by muse, mutect2, varscan2
- NUTM2G | c.54T>A p.P18= | Silent (SNP) | VAF 23/34 reads (68%) | catalogued as COSV100673002; called by muse, mutect2, varscan2
- NXPE4 | c.147C>A p.S49= | Silent (SNP) | VAF 83/216 reads (38%) | catalogued as COSV100970591; called by muse, mutect2, varscan2
- OBSL1 | c.2901G>A p.E967= | Silent (SNP) | VAF 5/100 reads (5%) | catalogued as rs1325028203, COSV99217498; called by muse, mutect2
- OR1L1 | c.348G>T p.L116= (on ENST00000373686; = p.L66= on NM_001005236.3) | Silent (SNP) | VAF 78/130 reads (60%) | catalogued as COSV100542295; called by muse, mutect2, varscan2
- OR4C6 | c.396C>T p.I132= | Silent (SNP) | VAF 27/135 reads (20%) | catalogued as COSV58606362; called by muse, mutect2, varscan2
- OR5AC2 | c.81C>A p.V27= | Silent (SNP) | VAF 140/499 reads (28%) | catalogued as COSV100684543; called by muse, mutect2, varscan2
- PDE1A | c.105A>G p.L35= | Silent (SNP) | VAF 24/67 reads (36%) | catalogued as rs142681796; called by muse, mutect2, varscan2
- PEAK1 | c.2442A>T p.P814= | Silent (SNP) | VAF 41/70 reads (59%) | catalogued as COSV100433554; called by muse, mutect2, varscan2
- PKHD1L1 | c.4569A>G p.G1523= | Silent (SNP) | VAF 35/41 reads (85%) | catalogued as COSV101007058; called by muse, mutect2, varscan2
- PLCH2 | c.603C>G p.L201= | Silent (SNP) | VAF 25/99 reads (25%) | catalogued as COSV99617432; called by muse, mutect2, varscan2
- PLEC | c.9213G>T p.T3071= (on ENST00000322810 / NM_201380.4; = p.T2961= on NM_000445.5) | Silent (SNP) | VAF 127/160 reads (79%) | catalogued as COSV100518481; called by muse, mutect2, varscan2
- PPP1R3A | c.801A>G p.V267= | Silent (SNP) | VAF 5/43 reads (12%) | catalogued as COSV99494692; called by muse, mutect2, varscan2
- R3HDM1 | c.459A>G p.L153= | Silent (SNP) | VAF 10/33 reads (30%) | catalogued as rs561808519, COSV99927007; called by muse, mutect2, varscan2
- RC3H1 | c.2181G>A p.Q727= | Silent (SNP) | VAF 61/159 reads (38%) | catalogued as COSV99281899; called by muse, mutect2, varscan2
- RSF1 | c.2988G>A p.K996= | Silent (SNP) | VAF 17/62 reads (27%) | catalogued as COSV100408104, COSV57838987; called by mutect2, varscan2
- SCAND1 | c.438G>A p.Q146= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as rs1368441196, COSV100019026; called by muse, mutect2
- SHC1 | c.81G>T p.G27= | Silent (SNP) | VAF 32/80 reads (40%) | catalogued as COSV100460560; called by muse, mutect2, varscan2
- SIMC1 | c.1794C>T p.N598= (on ENST00000443967 / NM_001308196.1; = p.N183= on NM_198567.5) | Silent (SNP) | VAF 58/102 reads (57%) | catalogued as COSV100231454; called by muse, mutect2, varscan2
- SLC22A6 | c.57C>T p.I19= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as COSV64560756; called by mutect2, varscan2
- SMPD1 | c.939A>T p.P313= | Silent (SNP) | VAF 26/41 reads (63%) | catalogued as COSV100193202; called by muse, mutect2, varscan2
- SNX7 | c.544A>C p.R182= | Silent (SNP) | VAF 33/99 reads (33%) | catalogued as COSV100069555; called by muse, mutect2, varscan2
- SORL1 | c.4839A>T p.V1613= | Silent (SNP) | VAF 112/288 reads (39%) | catalogued as COSV99495807; called by muse, mutect2, varscan2
- SYNE2 | c.6930A>G p.L2310= | Silent (SNP) | VAF 72/101 reads (71%) | catalogued as COSV100648623; called by muse, mutect2, varscan2
- TEX15 | c.6561A>G p.P2187= (on ENST00000256246; = p.P2570= on NM_001350162.2) | Silent (SNP) | VAF 134/199 reads (67%) | catalogued as rs1252372777, COSV99822350; called by muse, mutect2, varscan2
- TGFBRAP1 | c.894C>A p.I298= | Silent (SNP) | VAF 13/75 reads (17%) | catalogued as rs923483752, COSV51511865, COSV99305651; called by muse, mutect2, varscan2
- TRIM10 | c.693G>A p.R231= | Silent (SNP) | VAF 152/235 reads (65%) | catalogued as COSV100939225; called by muse, mutect2, varscan2
- YIPF2 | c.426G>C p.T142= | Silent (SNP) | VAF 19/35 reads (54%) | catalogued as COSV99450412; called by muse, mutect2, varscan2
- ZNF804A | c.3504G>A p.Q1168= | Silent (SNP) | VAF 84/213 reads (39%) | catalogued as COSV100170701; called by muse, mutect2, varscan2
- AL353804.7 | chrX:73848227 G>C | 5'Flank (SNP) | VAF 5/13 reads (38%) | called by muse, mutect2, varscan2
- AP4S1 | c.306+4269G>T | Intron (SNP) | VAF 60/102 reads (59%) | catalogued as COSV99364446; called by muse, mutect2, varscan2
- BTN2A3P | n.1392G>T | RNA (SNP) | VAF 93/225 reads (41%) | called by muse, mutect2, varscan2
- DDC | c.944+2416G>C | Intron (SNP) | VAF 10/35 reads (29%) | catalogued as COSV100779838; called by muse, mutect2, varscan2
- GRIN1 | c.*272G>T | 3'UTR (SNP) | VAF 42/67 reads (63%) | catalogued as COSV59294282; called by muse, mutect2, varscan2
- HERC2P3 | n.494G>T | RNA (SNP) | VAF 9/33 reads (27%) | catalogued as rs1203339480; called by muse, mutect2, varscan2
- HMGB1P1 | n.150G>C | RNA (SNP) | VAF 69/234 reads (29%) | called by muse, mutect2, varscan2
- IGKV1-13 | n.236G>A | RNA (SNP) | VAF 86/281 reads (31%) | called by muse, mutect2, varscan2
- L2HGDH | chr14:50237698 C>T | 3'Flank (SNP) | VAF 7/9 reads (78%) | catalogued as COSV99910649; called by muse, mutect2, varscan2
- MIR522 | n.4del | RNA (DEL) | VAF 94/189 reads (50%) | called by mutect2, pindel, varscan2
- NXF5 | n.368G>A | RNA (SNP) | VAF 122/156 reads (78%) | catalogued as rs758335218, COSV53790638; called by muse, mutect2, varscan2
- TMEM164 | c.391-12006G>A | Intron (SNP) | VAF 32/42 reads (76%) | catalogued as rs1477252477, COSV99912260; called by muse, mutect2, varscan2
- ZNF688 | c.-493G>A | 5'UTR (SNP) | VAF 41/153 reads (27%) | catalogued as rs200966469, COSV99794431; called by muse, mutect2, varscan2
